MMRF case MMRF_1344 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/d694fdee-c5fb-4316-bb4b-fe28901ae548

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 66.2 years (24,170 days); ISS stage: I; Days to last known disease status: 1,418 days (3.9 years); Days to last follow up: 1,418 days (3.9 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 100 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 106 days; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 169 days; Days to treatment end: 169 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 361 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 138 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 6.35 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 2.48 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.7 mg/dL.
- Day 64 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.27 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.4 g/L; Beta 2 Microglobulin 2.08 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 7.2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 6.9 g/dL; Glucose 6.71 mmol/L.
- Day 204 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.26 mg/dL; Immunoglobulin G 5.96 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 2.13 µg/mL; Lactate Dehydrogenase 8.97 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 4.9 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 5.72 mmol/L.
- Day 267 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.19 mg/dL; Immunoglobulin G 5.71 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 3 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.13 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 7.65 mmol/L.
- Day 365 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.28 mg/dL; Immunoglobulin G 7.55 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.2 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 8.1 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 177 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 456 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 7.65 g/L; Immunoglobulin A 0.24 g/L; Immunoglobulin M 0.55 g/L; Beta 2 Microglobulin 2.9 µg/mL; Lactate Dehydrogenase 3 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.2 g/dL; Glucose 6.66 mmol/L.
- Day 547 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.16 mg/dL; Immunoglobulin G 8.24 g/L; Immunoglobulin A 0.41 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.79 µg/mL; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 8.57 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 8.58 mmol/L.
- Day 638 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 8.98 g/L; Immunoglobulin A 0.46 g/L; Immunoglobulin M 0.44 g/L; Beta 2 Microglobulin 1.88 µg/mL; Lactate Dehydrogenase 2.52 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 129 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.13 mmol/L; Albumin 32 g/L; Total Protein 6.8 g/dL; Glucose 7.26 mmol/L.
- Day 729 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.89 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.88 mg/dL; Immunoglobulin G 8.57 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.38 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.87 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.3 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 7 g/dL; Glucose 7.81 mmol/L.
- Day 813 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.767 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 8.24 g/L; Immunoglobulin A 0.528 g/L; Immunoglobulin M 0.409 g/L; Beta 2 Microglobulin 1.97 µg/mL; Lactate Dehydrogenase 2.32 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 131 ×10⁹/L; Creatinine 69.8 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 10.9 mmol/L.
- Day 907 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 7.65 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.267 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.7 µkat/L; Hemoglobin 8.8 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.15 mmol/L; Albumin 31 g/L; Total Protein 6.4 g/dL; Glucose 8.31 mmol/L.
- Day 1,004 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 8.77 g/L; Immunoglobulin A 0.71 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 2.38 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 1.93 mmol/L; Albumin 31 g/L; Total Protein 6.4 g/dL; Glucose 9.13 mmol/L.
- Day 1,089 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.05 mg/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 0.67 g/L; Immunoglobulin M 0.24 g/L; Beta 2 Microglobulin 2.5 µg/mL; Lactate Dehydrogenase 2.78 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.23 mmol/L; Albumin 32 g/L; Total Protein 6.3 g/dL; Glucose 7.04 mmol/L.
- Day 1,152 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.62 mg/dL; Immunoglobulin G 8.37 g/L; Immunoglobulin A 1.12 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 1.93 mmol/L; Albumin 31 g/L; Total Protein 6.3 g/dL; Glucose 8.8 mmol/L.
- Day 1,250 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.47 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.959 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 2.34 µg/mL; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 125 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 31 g/L; Total Protein 6.1 g/dL; Glucose 14.7 mmol/L.
- Day 1,354 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.3 mg/dL; Immunoglobulin G 9.87 g/L; Immunoglobulin A 2.09 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 2.62 µg/mL; Lactate Dehydrogenase 3.13 µkat/L; Hemoglobin 8.93 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 9.13 mmol/L.
- Day 1,418 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 11.8 g/L; Immunoglobulin A 1.98 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 2.51 µg/mL; Lactate Dehydrogenase 1.72 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.05 mmol/L; Albumin 33 g/L; Total Protein 6.7 g/dL; Glucose 7.87 mmol/L.

Other clinical attributes
- Day 1: Weight: 77 kg; Height: 160 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1344_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1344_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
